Gene-level copy-number profile of tumor specimen AP-VLXG-T4 from APOLLO case AP-VLXG, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3.
Specimen AP-VLXG-T4: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a7c55ee8-b119-4b13-b0b7-7fbf544a6c4b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-VLXG-8V (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/ccaa4855-f108-4bd6-ac5d-b7ceae67f098

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,046; copy number 2: 6,006; copy number 3: 24,075; copy number 4: 17,758; copy number 5: 4,324; copy number 6: 2,972; copy number 7: 1,430; copy number 8: 611; copy number 9: 124; copy number 11: 52.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,217 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–156,140,089, 577 genes, copy number 7–11 (broad region; genes not listed).
- chr1:170,115,636–171,251,857, 16 genes, copy number 7 (within-gene range 6–7): SIGLEC30P, METTL11B, MIR3119-2, MIR3119-1, LINC01681, ISCUP1, LINC01142, HAUS4P1, GORAB-AS1, GORAB, AL162399.1, AL023495.1, PRRX1, Z97200.1, BX284613.2, MROH9.
- chr1:175,067,833–175,192,999, 2 genes, copy number 7: TNN, KIAA0040.
- chr1:207,801,518–207,879,115, 3 genes, copy number 8 (within-gene range 6–8): MIR29B2CHG, MIR29C, MIR29B2.
- chr1:212,545,694–212,556,065, 1 gene, copy number 7: LINC01740.
- chr5:58,198–28,287,807, 414 genes, copy number 7–8 (broad region; genes not listed).
- chr7:17,679,549–17,940,501, 2 genes, copy number 7: AC006482.1, SNX13.
- chr7:155,611,231–155,812,463, 3 genes, copy number 7: AC009403.1, RBM33, SHH.
- chr8:49,086,301–77,537,290, 401 genes, copy number 7–8 (broad region; genes not listed).
- chr8:79,259,402–81,924,348, 68 genes, copy number 7 (broad region; genes not listed).
- chr8:82,098,451–82,292,379, 2 genes, copy number 7: LINC02839, HNRNPA1P4.
- chr8:90,791,741–103,501,895, 268 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr8:115,408,496–115,809,673, 1 gene, copy number 7 (within-gene range 6–7): TRPS1.
- chr8:115,950,511–119,245,673, 30 genes, copy number 7 (within-gene range 6–7): LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16, EXT1, SAMD12, AC023590.1, SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2.
- chr8:120,380,761–128,564,679, 135 genes, copy number 7 (broad region; genes not listed).
- chr8:129,728,744–130,443,674, 17 genes, copy number 7: MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1.
- chr8:131,904,093–134,979,279, 54 genes, copy number 7: EFR3A, OC90, AC100868.1, HHLA1, KCNQ3, HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3, AC110741.2, AC105180.2, AC105180.1, ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3, AC087045.1, AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56.
- chr8:139,460,062–141,507,230, 36 genes, copy number 7: AC087354.1, AC090093.1, KCNK9, TRAPPC9, AC021744.1, C8orf17, AC040978.1, PEG13, AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD, PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2, PTP4A3, MROH5, AC100803.4, AC100803.1, HNRNPA1P38.
- chr8:142,611,049–145,066,685, 158 genes, copy number 7 (broad region; genes not listed).
- chr9:12,134–110,138, 8 genes, copy number 7: DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1, AL449043.1.
- chr20:31,465,506–31,870,747, 21 genes, copy number 7 (within-gene range 4–7): DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15.

Autosomal genes at a single copy (total copy number 1): 914. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
